FM case AD5469 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/277c9353-2261-4ff6-922b-40a875dcfb6a

Female, 52.1 years: Papillary renal cell carcinoma (ICD-O-3 8260/3) of the kidney; metastasis biopsied or resected from the mediastinum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
